Gene-level copy-number profile of tumor specimen ALCH-AELD-TTP1-A from ALCHEMIST case ALCH-AELD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.9 years (25,900 days).
Specimen ALCH-AELD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file daebb940-f830-4420-aae2-c3e80bab7c85.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AELD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/0b6b60df-931a-4bb8-b6a9-7fc76358750d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 270; copy number 2: 14,673; copy number 3: 14,397; copy number 4: 11,361; copy number 5: 13,520; copy number 6: 2,570; copy number 7: 1,259; copy number 8: 215; copy number 9: 45; copy number 10: 17; copy number 11: 1; copy number 12: 8; copy number 14: 1; copy number 16: 14; copy number 19: 25.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,529,488–11,771,350, 4 genes (within-gene range 0–2): AC022001.1, VGLL4, AC022001.2, AC022001.3.
- chr3:126,160,283–126,160,445, 1 gene (within-gene range 0–2): RNU1-30P.
- chr6:1,609,915–1,613,897, 1 gene: FOXC1.
- chr19:186,373–474,983, 13 genes: SEPTIN14P19, CICP19, LINC01002, RNU6-1076P, PLPP2, MIER2, AC016588.1, THEG, AC010641.1, C2CD4C, SHC2, RNA5SP462, ODF3L2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17,674 genes in 54 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,345,661–248,937,043, 2,325 genes, copy number 5–11 (broad region; genes not listed).
- chr2:20,667,144–21,970,959, 15 genes, copy number 6 (within-gene range 2–6): GDF7, AC012065.3, LDAH, LINC02850, AC115619.1, APOB, AC010872.1, TDRD15, AC067959.1, AC018742.1, AC011752.1, NUTF2P8, AC009411.2, AC009411.1, LINC01822.
- chr2:94,725,674–114,420,302, 477 genes, copy number 5 (broad region; genes not listed).
- chr2:142,131,178–201,480,846, 788 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr3:155,024,124–181,836,880, 369 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:182,365,147–198,123,232, 372 genes, copy number 5 (broad region; genes not listed).
- chr4:45,995,119–57,605,872, 180 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr4:67,737,118–71,572,087, 107 genes, copy number 5–9 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 5–6 (broad region; genes not listed).
- chr6:1,623,806–23,031,780, 324 genes, copy number 5–19 (within-gene range 5–24) (broad region; genes not listed).
- chr6:39,299,001–55,940,624, 331 genes, copy number 5 (broad region; genes not listed).
- chr6:75,921,114–78,606,036, 14 genes, copy number 5: IMPG1, Y_RNA, RNU6-248P, RNU6-261P, LINC02540, RNU6-84P, AL591030.1, AL590426.1, AL355612.1, AL365222.1, HTR1B, RPS6P7, MEI4, AL121718.1.
- chr7:73,680,918–148,698,664, 1,404 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:148,807,383–159,233,377, 222 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,494 genes, copy number 5–6 (broad region; genes not listed).
- chr10:14,061–8,016,631, 145 genes, copy number 5 (broad region; genes not listed).
- chr10:16,005,808–23,442,390, 116 genes, copy number 5 (broad region; genes not listed).
- chr11:86,649–36,465,204, 900 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr11:48,216,810–49,379,669, 42 genes, copy number 7–19: OR4B1, OR4B2P, OR4X2, OR4X1, OR4S1, OR4C3, OR4C4P, OR4C5, OR4C2P, OR4C10P, OR4C9P, OR4R1P, OR4A47, OR4A48P, OR4A46P, OR4A40P, OR4A43P, OR4A45P, OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP, AC027369.2, TRIM51GP, TRIM53CP, AC027369.1, TRIM49B, TRIM64C, AC084851.3, AC084851.1, UBTFL7, AC084851.2, AC118273.1, AC118273.2, TRIM77BP, UBTFL9, FOLH1, AC118942.1.
- chr11:55,279,447–79,441,030, 1,072 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:86,153,227–104,164,379, 320 genes, copy number 5 (broad region; genes not listed).
- chr11:108,157,215–111,926,871, 68 genes, copy number 5 (broad region; genes not listed).
- chr11:116,773,799–117,316,259, 25 genes, copy number 5 (within-gene range 2–5): ZPR1, APOA5, AP006216.2, AP006216.3, APOA4, APOC3, APOA1, APOA1-AS, SIK3, RNY4P6, AP000936.3, AP000936.1, AP000936.2, AP005018.2, AP005018.1, PAFAH1B2, SIDT2, TAGLN, PCSK7, AP000892.4, RNF214, AP000892.2, BACE1, BACE1-AS, AP000892.3.
- chr12:66,767–17,709,867, 541 genes, copy number 5 (broad region; genes not listed).
- chr12:104,303,739–133,238,549, 745 genes, copy number 5 (broad region; genes not listed).
- chr13:108,596,152–114,337,626, 116 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–25,156,314, 472 genes, copy number 6 (broad region; genes not listed).
- chr15:62,390,526–66,565,979, 121 genes, copy number 6 (broad region; genes not listed).
- chr16:31,060,843–31,150,083, 14 genes, copy number 6 (within-gene range 4–6): ZNF668, AC135050.4, ZNF646, PRSS53, AC135050.2, VKORC1, AC135050.7, BCKDK, KAT8, AC135050.5, AC135050.6, AC009088.3, PRSS8, PRSS36.
- chr16:33,687,025–34,163,110, 30 genes, copy number 5–9: BMS1P8, ENPP7P13, AC136428.2, IGHV3OR16-12, AC136428.3, IGHV3OR16-13, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3, ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5, AC133561.1, BCAP31P1, AC133561.2, AC133561.4, AC133561.3, AC136932.1, DUX4L45, PCMTD1P2, DUX4L46, DUX4L47, LINC00273, RNA5-8SP2.
- chr16:79,212,711–88,537,031, 225 genes, copy number 5 (broad region; genes not listed).
- chr16:89,088,375–90,096,354, 49 genes, copy number 5: ACSF3, AC135782.3, LINC00304, LINC02138, CDH15, SLC22A31, AC009113.1, ZNF778, AC009113.2, ANKRD11, AC137932.3, AC137932.1, AC137932.2, AC092120.1, AC092120.3, RNU6-430P, AC092120.2, SPG7, AC092123.1, RPL13, SNORD68, CPNE7, DPEP1, CHMP1A, SPATA33, AC010538.1, CDK10, LINC02166, SPATA2L, VPS9D1, VPS9D1-AS1, ZNF276, FANCA, SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7.
- chr17:20,814,620–30,542,416, 253 genes, copy number 5–9 (broad region; genes not listed).
- chr17:54,968,727–83,240,804, 888 genes, copy number 5 (within-gene range 4–7) (broad region; genes not listed).
- chr19:2,328,615–5,340,803, 143 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr20:87,250–64,327,972, 1,401 genes, copy number 5 (broad region; genes not listed).
- chr21:7,744,962–8,880,976, 34 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1.
- chr21:40,863,994–44,262,216, 98 genes, copy number 5 (broad region; genes not listed).
- chr21:44,450,986–45,942,454, 71 genes, copy number 5 (broad region; genes not listed).
- chr22:15,282,557–26,968,763, 616 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 270. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
